Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A7EN, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A7EN-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

[REDACTED]

ICD-O-3
Leiomyosarcoma NOS
8890/3
Site Retroperitoneum
048.0
9/26/13

....

Clinical Diagnosis & History:
High grade leiomyosarcoma.

Specimens Submitted:

- 1: Left kidney, left colon and retroperitoneal mass
- 2: Intra abdominal blood clot
- 3: Splenic

DIAGNOSIS:

1. Soft tissue, Left kidney, left colon and retroperitoneum; resection:
- Leiomyosarcoma, high grade, with focal areas of necrosis (10% microscopic estimate).
- The tumor measures: 8.0 x 7.5 x 7.5 cm.
- The mitotic count is 40 MF/10 HPFs.
- The adjacent segment of colon and renal parenchyma are unremarkable
- Two benign lymph nodes in pericolic fibroadipose tissue (0/2)
- The tumor is covered grossly by a thin membranous layer of fibrous tissue, that shows focal disruption and a large defect with hemorrhagic changes (6x 3.5 cm). Microscopically the tumor extends closely to the inked surface.
- Colonic, renal vascular, and ureter margins are negative for tumor.

2. Blood clot, Intra abdominal; biopsy:
- Blood admixed with focal reactive mesothelial cells (see note). No tumor seen.

Note: The selected slides have been reviewed with

3. 'Spleen'; excision:
- Accessory spleen and peri-splenic soft tissue with subserosal edema and reactive changes.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

** Continued on next page **

[page 2 of 3]
Gross Description:

1). Received fresh is a piece of soft tissue labeled "left kidney, left colon and retroperitoneal mass". Specimen measures 12 x 11.5 x 10.4 cm and consists of kidney (10 x 7 x 4.2 cm) with two segments of attached ureters (9.4 cm), a segment of colon (12.4 cm) and a soft tissue mass (8 x 7.5 x 7.5 cm). The segment of colon shows unremarkable intestinal mucosa. Serial sectioning kidney reveals unremarkable renal parenchyma. Two ureters (see photo) are kinked due to adventitia adhesion to adjacent tumor mass resulting dilatation of proximal segments of ureters (0.5 cm in diameter). No gross involvement of ureteral muscular wall is seen. No adrenal gland is identified. The retroperitoneal mass is situated in the mesentery adipose tissue with no extension into adjacent colon or kidney. There is a large defect area (6 x 3.5 cm) with associated hemorrhage. Serially sections reveal a well circumscribed mass, covered by a layer of fibrous tissue (surface inked blue) with disruption and previously described defect. The mass appears white, soft and flesh with no appreciable necrosis seen. However, marked hemorrhage is noted with blood clots present at the peripheral of mass and mesenteric soft tissue, where defect is located. Portion of lesion is submitted to TPS.

Summary of blocks:

CM1-colon margin1
CM2-colon margin2
C-colonic mucosa
RM-renal hilar vascular margin and ureter margins
K-kidney
TU-tumor to ureters
TM-tumor to surface margin
TC-tumor to colon
T-tumor (including hemorrhagic defective area)

2) The specimen is received in formalin, labeled, "Intra-abdominal blood clot", and consists of multiple brown organized blood clots measuring in aggregate 5.5 x 4.0 x 2.0 cm. The specimen is photographed and representatively submitted.

Summary of sections:

U - undesignated

3) The specimen is received in formalin, labeled, "Splenic", and consists of a tan-brown firm nodule measuring 1.0 x 0.7 x 0.6 cm with a smooth external surface. Attached to the nodule is yellow fatty tissue measuring 1.0 x 0.5 x 0.2 cm. On sectioning, the nodule reveals a brown homogenous cut surface. The specimen is photographed. The nodule is trisected and entirely submitted.

Summary of sections:

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

U - undesignated

Page 3 of 3

Summary of Sections:

Part 1: Left kidney, left colon and retroperitoneal mass

Block	Sect.	Site	PCs
1	C		1
1	CM1		2
1	CM2		2
1	K		1
1	RM		4
5	T		8
1	TC		1
1	TM		1
1	TU		1

Part 2: Intra abdominal blood clot

Block	Sect.	Site	PCs
1	U		3

Part 3: Splenic

Block	Sect.	Site	PCs
1	U		2

** End of Report **

Source: NCI Genomic Data Commons file d7e5fb94-e72e-4371-9103-11c6d9619fac (TCGA-DX-A7EN.FE7C572A-1310-4BEA-B8A7-798915D09913.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).